Surgical pathology report (de-identified scan), TCGA case TCGA-AZ-4615, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-AZ-4615-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: GALLBLADDER, LAPAROSCOPIC CHOLECYSTECTOMY -

- A. CHOLELITHIASIS AND CHRONIC CHOLECYSTITIS WITH ASSOCIATED ULCERATION AND INTRAMURAL HISTIOCYTIC INFLAMMATORY INFILTRATE.
- B. NO EVIDENCE OF MALIGNANCY.

TCGA-AZ-4615

PART 2: RIGHT COLON, APPENDIX, AND TERMINAL ILEUM, RIGHT HEMICOLECTOMY -

- A. ULCERATED, INVASIVE, MODERATELY TO FOCALLY POORLY DIFFERENTIATED COLONIC ADENOCARCINOMA, 4 CM, ARISING IN THE CECUM IMMEDIATELY ADJACENT TO THE ILEOCECAL VALVE. CARCINOMA INFILTRATES THROUGH THE MUSCULARIS PROPRIA AND FOCALLY EXTENDS INTO THE COLONIC AND APPENDICEAL SUBSEROSA TO WITHIN LESS THAN 0.5 CM BEYOND THE BORDER WITH THE MUSCULARIS PROPRIA (SECTION 2D). CARCINOMA EXTENDS INTO AND OBSTRUCTS THE APPENDICEAL ORIFICE/LUMEN (SLIDES 2F-2H).
- B. PRESUMED ANGIOLYMPHATIC INVASION PRESENT (See diagnosis 2G).
- C. NON-NEOPLASTIC COLON WITH NO SIGNIFICANT HISTOPATHOLOGIC ABNORMALITY.
- D. BENIGN TERMINAL ILEUM WITH NO SIGNIFICANT HISTOPATHOLOGIC ABNORMALITY.
- E. PROXIMAL APPENDIX WITH OBSTRUCTION BY CARCINOMA ASSOCIATED WITH A MUCINOUS CARCINOMA COMPONENT WITHIN THE APPENDICEAL LUMEN, AND ASSOCIATED ACUTE AND ORGANIZING APPENDICITIS / PERIAPPENDICITIS.
- F. BENIGN SURGICAL RESECTION MARGINS AND SEROSAL SURFACES.
- G. METASTATIC ADENOCARCINOMA IS PRESENT IN ONE OF EIGHTEEN (1/18) REGIONAL LYMPH NODES (SLIDE 2N). METASTATIC FOCUS MEASURES 0.4 CM. NO EXTRACAPSULAR EXTENSION IS IDENTIFIED.
- H. TNM PATHOLOGIC STAGE: T3a/b, N1, MX (See synoptic).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY COLON, RECTAL, APPENDIX TUMORS

SPECIMEN TYPE: Right hemicolectomy

SPECIMEN LENGTH: 31 cm

TUMOR SITE: Cecum

TUMOR CONFIGURATION: Ulcerating

TUMOR SIZE: Greatest dimension: 4 cm
Additional dimensions: 3 x 3 cm

INTACTNESS OF MESORECTUM: Not applicable

HISTOLOGIC TYPE: Adenocarcinoma

HISTOLOGIC GRADE: High-grade (poorly differentiated to undifferentiated)

PATHOLOGIC STAGING (pTNM): pT3a/b

pN1

Number of nodes examined: 18

Number of nodes involved: 1

pMX

Treatment: Untreated

MARGINS:

Proximal margin uninvolved by invasive carcinoma

Distal margin uninvolved by invasive carcinoma

Circumferential (radial) margin - Not applicable

Mesenteric margin uninvolved by invasive carcinoma

If all margins uninvolved by invasive carcinoma: distance of invasive carcinoma from closest margin: 50 mm

Margin: Mesenteric

ANGIOLYMPHATIC INVASION:

Present

PERINEURAL INVASION:

Absent

TUMOR BORDER CONFIGURATION: Infiltrating

ADDITIONAL TUMOR CHARACTERISTICS: None

ADDITIONAL PATH FINDINGS (check all that apply):

Other: Appendiceal obstruction by tumor with acute appendicitis

Source: NCI Genomic Data Commons file 3eccb334-09f2-43d7-8f1f-e9962de51e1d (TCGA-AZ-4615.EE4EA571-2DC8-470A-A442-291C85200546.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).